Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UA-01A (Primary Tumor).

[page 1 of 2]
HPV Discrepancy		/
Discrepancy Primary Noted		/

100-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1 *hw* 5/1/11

Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

cc:

Client: [REDACTED]

Location: [REDACTED]

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Endometrial cancer

Postoperative Dx: {Not Provided}

Specimen(s) Received:

A: Right tube and ovary

B: Left tube and ovary

C: Uterus, cervix

DIAGNOSIS:

A. Right tube and ovary:

1. Ovary with physiologic changes
2. Acute salpingitis
3. Free of tumor

B. Left tube and ovary:

1. Ovary with physiologic changes
2. Acute salpingitis
3. Free of tumor

C. Uterus, cervix:

ENDOMETRIAL ADENOCARCINOMA, endometrioid type; well differentiated (FIGO grade I)

Tumor Information:

Type of specimen:

Hysterectomy

Tumor location:

Endometrium

Tumor size:

3.5 x 2.0 x 1.0 cm

Histologic type:

Endometrioid

Histologic grade:

Well differentiated (FIGO grade 1)

Tumor extent:

Depth of invasion:

0.4 cm out of a 1.5 cm thick myometrium (<1/3 of the myometrial thickness)

Horizontal extent:

3.5 cm

Lower third of vagina involvement:

N/A

Lower uterine segment involvement:

Not present

Pelvic wall extension:

Not present

Parametrial invasion:

Not present

Bladder/rectal mucosal extension:

N/A

Lymphovascular invasion:

None identified

Resection margins:

Free of involvement

Lymph node involvement:

N/A

Regulatory Statement

The following statement may be appended to some of the requests and/or used in developing the above report. This text was developed and its performance characteristics determined by the Food and Drug Administration. The FDA has determined that such statement or approval is not necessary. This text is used for reference purposes. It should not be regarded as a recommendation for use. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
1

Surgical Pathology Report

Other findings:

Adenomyosis

Comments:

has reviewed this case and concurs.

Intraoperative Consultation:

C. Frozen Section Interpretation: Endometrial adenocarcinoma, well differentiated; possible myometrial invasion

Gross Description

- A. Received in formalin labeled "right tube and ovary" consists of an ovary attached fallopian tube weighing 7 grams. The ovary is tan measuring 2.0 cm in greatest dimensions. Cut surface is unremarkable. The fallopian tube measures 5.0 cm in length and 0.3 cm in diameter. Representative sections are submitted in cassette A.
- B. Received in formalin labeled "left tube and ovary" consists of an ovary and attached fallopian tube weighing 7 grams. The ovary is tan measuring 1.5 cm in greatest dimensions. Cut sections are unremarkable. The attached fallopian tube measures 4.0 cm in length and 0.5 cm in diameter. Representative sections are submitted in cassette B.
- C. Received fresh labeled "cervix and uterus" consists of a uterus and cervix weighing 57 grams. The uterus is received bivalved. The uterine corpus measures 5.0 x 4.5 x 3.5 cm. The serosal surface is tan and smooth. The cervix measures 3.0 cm in length and 3.0 cm in diameter. The ectocervical mucosa is white-tan and smooth. A tan polypoid mass is present on the endometrial surface measuring approximately 3.5 x 2.0 cm in area. The tumor measures 1.0 cm in thickness. Possible myometrial invasion is identified grossly. A portion of tissue is submitted for frozen section, < 1/2 of myometrial thickness. The myometrium measures approximately 1.5 cm in thickness. The endocervical canal is unremarkable grossly. The myometrium is serially sectioned to reveal a well-circumscribed tan mass measuring 0.7 cm in greatest dimension. Representative sections are submitted as follows:

KEY TO CASSETTES:

- | | | |
|-------|---|---|
| C1 | - | Frozen section residual |
| C2 | - | Cervix |
| C3 | - | Lower uterine segment |
| C4 | - | Anterior endometrium |
| C5-C7 | - | Anterior endo/myometrium, full thickness |
| C8-C9 | - | Posterior endo/myometrium, full thickness |
| C10 | - | Myometrial mass and serosa |
| C11 | - | Parametrial tissue |

Microscopic Description

A-C. The microscopic findings support the above diagnoses.

[REDACTED]

Source: NCI Genomic Data Commons file 4297de0e-01e0-4724-a6b6-5a633a554224 (TCGA-BS-A0UA.58DC7332-5100-408B-9A1E-F0282B013648.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).